Somatic mutation profile of tumor specimen 3fdf0dbe-e05c-465f-8bed-4a92dd (aliquot 3fdf0dbe-e05c-465f-8bed-4a92dd_D6_1) from CPTAC case 11BR031, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 50.5 years (18,432 days).
Specimen 3fdf0dbe-e05c-465f-8bed-4a92dd: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56244ecb-799a-4650-a3b3-4dbbcc9f57bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 567b7b28-c132-4d78-a181-e2d340 (Blood Derived Normal), aliquot 567b7b28-c132-4d78-a181-e2d340_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c99c1bfc-3d58-405b-bf72-bf5bc9571f6c

The open-access MAF lists 353 somatic variants for this specimen: 235 protein-altering or splice-affecting, 86 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 86, Nonsense Mutation 23, Intron 17, 3'UTR 7, Splice Site 5, RNA 4, Frame Shift Del 3, Splice Region 3, 3'Flank 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNB1 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555889130, CM1511116, COSV65569863; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.4495C>T p.Q1499* | Nonsense Mutation (SNP) | VAF 26/334 reads (8%) | catalogued as rs797045760, COSV56966997, COSV99239299; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 73/220 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 17/218 reads (8%) | catalogued as HM971826, COSV99497125; called by muse, mutect2
- ACIN1 | c.3691G>A p.D1231N | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1331988953; called by muse, mutect2, varscan2
- ADGRE1 | c.1123-1G>C p.X375_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV51672084; called by muse, mutect2, varscan2
- ANK2 | c.7865C>T p.S2622L | Missense Mutation (SNP) | VAF 79/395 reads (20%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.019); catalogued as COSV52179409; called by muse, mutect2, varscan2
- ANKRD11 | c.1576C>T p.H526Y | Missense Mutation (SNP) | VAF 111/577 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1318137276, COSV56363032; called by muse, mutect2, varscan2
- ASIC3 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1033732217, COSV52522152; called by muse, mutect2
- BOD1L1 | c.6552G>C p.L2184F | Missense Mutation (SNP) | VAF 65/341 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV50055595; called by muse, mutect2, varscan2
- CCN5 | c.184G>T p.E62* | Nonsense Mutation (SNP) | VAF 39/352 reads (11%) | catalogued as COSV51936118, COSV51937228; called by muse, mutect2, varscan2
- CNOT6L | c.1476C>G p.F492L (on ENST00000504123 / NM_001286790.2; = p.F487L on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV53702788, COSV99362350; called by muse, mutect2, varscan2
- DCAF8 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs1173427133, COSV100470483; called by muse, mutect2
- DCAF8L2 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 62/373 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV101446080; called by muse, mutect2, varscan2
- DSE | c.1895C>T p.S632L | Missense Mutation (SNP) | VAF 32/510 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.165); catalogued as rs768151620; called by muse, mutect2
- ELANE | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 10/308 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs375350474, COSV52255082; called by muse, mutect2
- ELP1 | c.2006C>T p.S669L | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); catalogued as COSV65896180; called by muse, mutect2
- ENDOD1 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 55/356 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs1477323248; called by muse, mutect2, varscan2
- FAM209B | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 20/569 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as rs1421848670; called by muse, mutect2
- FAT3 | c.5590G>A p.E1864K | Missense Mutation (SNP) | VAF 118/387 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as rs766878907; called by muse, mutect2, varscan2
- FCRL5 | c.2434G>C p.E812Q | Missense Mutation (SNP) | VAF 40/287 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as rs779276501, COSV100708969; called by muse, mutect2, varscan2
- FLG | c.10484C>T p.S3495L | Missense Mutation (SNP) | VAF 151/1194 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64251222; called by muse, mutect2, varscan2
- FOXG1 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 107/557 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as COSV100487033; called by muse, mutect2, varscan2
- GPR157 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66233804; called by muse, mutect2
- H2BC6 | c.338C>G p.S113* | Nonsense Mutation (SNP) | VAF 21/310 reads (7%) | catalogued as COSV61591163; called by muse, mutect2
- HCAR1 | c.826del p.L276Wfs*22 | Frame Shift Del (DEL) | VAF 65/303 reads (21%) | catalogued as rs764246177; called by mutect2, pindel, varscan2
- HERC1 | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 24/190 reads (13%) | catalogued as rs774088719, COSV71248938; called by mutect2, varscan2
- HNRNPA3 | c.914G>C p.G305A | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as COSV66820825; called by muse, mutect2, varscan2
- HOXB9 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.072); catalogued as rs199882905; ClinVar: likely benign; called by muse, mutect2, varscan2
- HSPA14 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV65683857; called by muse, mutect2, varscan2
- HSPA4L | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV56544015; called by muse, mutect2, varscan2
- ICAM5 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as rs1235315412, COSV99703072; called by muse, mutect2, varscan2
- IRF6 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 28/682 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM022391; called by muse, mutect2
- ITIH3 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs376872714; called by muse, mutect2, varscan2
- IWS1 | c.766C>G p.P256A | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.024); catalogued as rs944448133; called by muse, mutect2, varscan2
- KDM5B | c.235G>C p.D79H | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99350864; called by muse, mutect2, varscan2
- KIF26B | c.4409C>T p.S1470L | Missense Mutation (SNP) | VAF 31/316 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1254298903; called by muse, mutect2, varscan2
- KMT2B | c.6079G>A p.E2027K | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs1404813734, COSV55858924; called by muse, mutect2, varscan2
- KRT2 | c.1212G>C p.Q404H | Missense Mutation (SNP) | VAF 44/1055 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100548592; called by muse, mutect2
- LAMB1 | c.5017G>A p.E1673K | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs751630523; called by muse, mutect2, varscan2
- LMBRD2 | c.429G>T p.K143N | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56949301; called by muse, mutect2
- LRFN2 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs768433587, COSV57825706; called by muse, mutect2, varscan2
- LRP1B | c.10276G>C p.E3426Q | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV67207161; called by muse, mutect2
- LRRC71 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 139/253 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs767696360; called by muse, mutect2, varscan2
- MACF1 | c.6433G>A p.E2145K | Missense Mutation (SNP) | VAF 25/167 reads (15%) | catalogued as rs1168393704; called by muse, mutect2, varscan2
- MED24 | c.1448-5C>T | Splice Region (SNP) | VAF 10/185 reads (5%) | catalogued as COSV62418890; called by muse, mutect2
- MUC16 | c.25430C>T p.A8477V | Missense Mutation (SNP) | VAF 71/426 reads (17%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs371479788; called by muse, mutect2, varscan2
- NADK | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV58268833; called by muse, mutect2
- NID2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 57/644 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs758004106; called by muse, mutect2
- OS9 | c.1095G>C p.L365F | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99067170; called by muse, mutect2
- OSTN | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1252664052, COSV59140016; called by muse, mutect2
- OTOA | c.1101G>A p.M367I (on ENST00000286149; = p.M353I on NM_144672.4) | Missense Mutation (SNP) | VAF 95/742 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs1286798511; called by muse, mutect2, varscan2
- P2RY12 | c.583C>G p.Q195E | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV56376379; called by muse, mutect2
- PAK3 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.216); catalogued as COSV53275469; called by muse, mutect2
- PARD3 | c.1209G>C p.Q403H | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV60751149; called by muse, mutect2, varscan2
- PCDH10 | c.1230G>T p.K410N | Missense Mutation (SNP) | VAF 86/426 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV99993180; called by muse, mutect2, varscan2
- PCDHB13 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 52/255 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.353); catalogued as COSV53395014, COSV53397448; called by muse, mutect2, varscan2
- PFKFB4 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 17/151 reads (11%) | PolyPhen benign (0.168); catalogued as COSV51683062; called by muse, mutect2, varscan2
- PHF3 | c.5194C>G p.Q1732E | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV99029803; called by muse, mutect2
- PIWIL1 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755410536; called by muse, mutect2, varscan2
- PKHD1 | c.6872C>G p.S2291* | Nonsense Mutation (SNP) | VAF 86/395 reads (22%) | catalogued as rs376444914; called by muse, mutect2, varscan2
- PLCE1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53342427; called by muse, mutect2
- PLEKHG5 | c.2451C>G p.F817L (on ENST00000400915 / NM_001042663.3; = p.F780L on NM_020631.6) | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100557175, COSV100557386; called by muse, mutect2
- POLM | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1348247032; called by muse, mutect2, varscan2
- PPIG | c.2108C>G p.S703C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as rs1295564673; called by muse, mutect2, varscan2
- PTX4 | c.341G>A p.R114Q (on ENST00000447419 / NM_001328608.2; = p.R109Q on NM_001013658.1) | Missense Mutation (SNP) | VAF 44/447 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs746933052, COSV53515379; called by muse, mutect2
- PURG | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99988130; called by muse, mutect2, varscan2
- RC3H1 | c.2794C>G p.Q932E | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV51207711; called by muse, mutect2, varscan2
- RGS11 | c.298G>A p.E100K (on ENST00000397770 / NM_183337.3; = p.E79K on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.574); catalogued as rs746825878; called by muse, mutect2, varscan2
- RP1 | c.1075T>C p.Y359H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1251452908; called by muse, mutect2, varscan2
- SCN9A | c.3482G>A p.W1161* (on ENST00000303354; = p.W1150* on NM_002977.3) | Nonsense Mutation (SNP) | VAF 10/76 reads (13%) | catalogued as rs759003928, COSV57615109; ClinVar: uncertain significance / benign; called by mutect2, varscan2
- SETD5 | c.3437C>G p.S1146* | Nonsense Mutation (SNP) | VAF 21/207 reads (10%) | catalogued as COSV100200756; called by muse, mutect2, varscan2
- SH3GL2 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV101014132; called by muse, mutect2
- SLC45A3 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 47/235 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as rs753484902, COSV100901344; called by muse, mutect2, varscan2
- SMYD1 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101352541; called by muse, mutect2
- STEAP2 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99840341; called by muse, mutect2, varscan2
- SYNE1 | c.14924G>C p.G4975A (on ENST00000367255 / NM_182961.4; = p.G4904A on NM_033071.3) | Missense Mutation (SNP) | VAF 85/391 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV55131202; called by muse, mutect2, varscan2
- SYNE1 | c.1798G>C p.E600Q (on ENST00000367255 / NM_182961.4; = p.E607Q on NM_033071.3) | Missense Mutation (SNP) | VAF 18/501 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54942861; called by muse, mutect2
- SYT10 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs776089898; called by muse, mutect2, varscan2
- TEX45 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1456064476; called by muse, mutect2
- THOC6 | c.153C>T p.F51= | Splice Region (SNP) | VAF 45/358 reads (13%) | catalogued as rs1402868546; called by muse, mutect2, varscan2
- TMEM141 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1259752885; called by muse, mutect2
- TMEM64 | c.992G>C p.R331P | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV69127704; called by muse, mutect2
- TMPRSS15 | c.2535G>A p.M845I | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as COSV53036295; called by muse, mutect2, varscan2
- TRAF1 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 30/436 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.317); catalogued as COSV65867737; called by muse, mutect2
- TRIM11 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV52856315; called by muse, mutect2, varscan2
- TRIOBP | c.6791C>T p.S2264L (on ENST00000644935 / NM_001039141.3; = p.S551L on NM_007032.5) | Missense Mutation (SNP) | VAF 128/794 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as rs566948219; called by muse, varscan2
- TRPC5 | c.2189G>C p.R730T | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99462639; called by muse, mutect2
- TSSC4 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.014); catalogued as COSV50187153; called by muse, mutect2, varscan2
- TTN | c.17903G>C p.R5968T (on ENST00000591111; = p.R5041T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/112 reads (9%) | PolyPhen benign (0); catalogued as COSV59957038, COSV60462793; called by muse, mutect2
- UBN1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs542572925; called by muse, mutect2, varscan2
- UBR4 | c.4120G>A p.E1374K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV64394201; called by muse, mutect2
- UNC45B | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.076); catalogued as rs767233706; called by muse, mutect2, varscan2
- WASHC5 | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 37/538 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.129); catalogued as rs768967879, COSV59198596; called by muse, mutect2
- WSCD1 | c.1724G>C p.R575T | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58494227; called by muse, mutect2, varscan2
- ZFPM1 | c.2837C>T p.P946L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1322890660, COSV60324262; called by muse, mutect2
- ZNF253 | c.554C>A p.S185* | Nonsense Mutation (SNP) | VAF 20/248 reads (8%) | catalogued as COSV100849436, COSV63036828; called by muse, mutect2
- ZNF443 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV100041967; called by muse, mutect2, varscan2
- ZNF467 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57373806; called by muse, mutect2, varscan2
- ZNF483 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 38/322 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.958); catalogued as rs774290739; called by muse, mutect2, varscan2
- ZNF641 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1167396208; called by muse, varscan2
- ABCC4 | c.3257C>T p.S1086L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ACVR2B | c.343C>G p.H115D | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.216); called by muse, mutect2
- AIFM3 | c.1583G>A p.G528E | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD18B | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- ANKRD36B | c.1298T>C p.L433S | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); called by muse, mutect2
- AP1G2 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 92/346 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- APAF1 | c.1234G>C p.E412Q (on ENST00000551964 / NM_181861.2; = p.E401Q on NM_001160.3) | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASPM | c.5170G>C p.E1724Q | Missense Mutation (SNP) | VAF 33/358 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2
- ATP8A1 | c.3196G>T p.D1066Y | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BBS5 | c.737C>G p.S246* | Nonsense Mutation (SNP) | VAF 47/284 reads (17%) | called by mutect2, varscan2
- BTBD8 | c.3451G>T p.E1151* (on ENST00000636805 / NM_001376131.1; = p.E638* on NM_015237.4) | Nonsense Mutation (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- C17orf80 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CACNB4 | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.222); called by muse, mutect2
- CCDC158 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC22 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- CCNI | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CEP250 | c.5821G>A p.E1941K | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CFAP65 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 48/277 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CFH | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 16/387 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2
- CLTC | c.2068C>G p.H690D | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CLTC | c.3376G>C p.D1126H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- COL12A1 | c.6520C>G p.L2174V | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE7 | c.633del p.N212Tfs*9 | Frame Shift Del (DEL) | VAF 116/235 reads (49%) | called by mutect2, pindel, varscan2
- CWF19L2 | c.2293C>T p.H765Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP27B1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 40/520 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.362); called by muse, mutect2
- DAB2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- DMAP1 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 17/296 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.932); called by muse, mutect2
- DNAH11 | c.8984G>C p.R2995T | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DNAH3 | c.5540G>A p.R1847K | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOP1A | c.2866G>C p.D956H | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- DPAGT1 | c.398C>A p.S133* | Nonsense Mutation (SNP) | VAF 30/544 reads (6%) | called by muse, mutect2
- DTNB | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2I2 | c.1428C>G p.I476M | Missense Mutation (SNP) | VAF 52/348 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- DZIP3 | c.2598C>G p.F866L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- E2F4 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2
- EFS | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 14/285 reads (5%) | called by muse, mutect2
- EGR2 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 16/329 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2
- EMP3 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERV3-1 | c.1468C>A p.Q490K | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- EXOC5 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- FAM104A | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- FAM13B | c.2091C>G p.I697M | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- FAM90A1 | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 34/690 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2
- FRAS1 | c.7291G>C p.D2431H | Missense Mutation (SNP) | VAF 21/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GLB1L | c.1858G>C p.D620H | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- GMFB | c.283+7G>A | Splice Region (SNP) | VAF 18/93 reads (19%) | called by muse, mutect2, varscan2
- GRHL3 | c.841-1G>C p.X281_splice (on ENST00000350501 / NM_198174.3; = p.X286_splice on NM_021180.3) | Splice Site (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- HDAC2 | c.1006G>C p.E336Q | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- HLA-F | c.828G>C p.Q276H | Missense Mutation (SNP) | VAF 66/530 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- HNRNPR | c.1832C>G p.S611C | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); called by muse, mutect2
- HSD17B11 | c.601G>C p.D201H | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.735); called by muse, mutect2
- HYDIN | c.2415C>G p.I805M | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KAT6A | c.4596G>A p.M1532I | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- KCNJ2 | c.315G>C p.L105F | Missense Mutation (SNP) | VAF 98/415 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- KDM5C | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.68); called by muse, mutect2
- KIF2C | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- LARP1 | c.437-1G>A p.X146_splice (on ENST00000518297 / NM_033551.3; = p.X69_splice on NM_015315.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- LRRC47 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.133); called by muse, mutect2
- LRRC4B | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 50/777 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRRTM1 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 9/148 reads (6%) | called by muse, mutect2
- LTBP2 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- MAP1B | c.3686C>G p.S1229C | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); called by muse, mutect2
- MEAK7 | c.172C>G p.L58V | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MEI1 | c.2771C>T p.S924L | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MPDZ | c.6136G>A p.E2046K (on ENST00000319217 / NM_001330637.2; = p.E2017K on NM_003829.5) | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MTCH1 | c.1118C>G p.S373C (on ENST00000373627 / NM_001271641.1; = p.S356C on NM_014341.2) | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MUCL3 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- MYC | c.894G>C p.K298N (on ENST00000377970; = p.K313N on NM_002467.6) | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MYO7A | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- NECAB1 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- NES | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 63/386 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NHS | c.2935C>A p.L979I | Missense Mutation (SNP) | VAF 76/577 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOTCH3 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 36/701 reads (5%) | called by muse, mutect2
- NR2F6 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- NUP54 | c.1297G>C p.E433Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OLFM3 | c.444G>C p.E148D (on ENST00000338858 / NM_001288821.1; = p.E128D on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR3A3 | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 44/282 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.053); called by muse, mutect2
- OR51C1P | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.026); called by muse, mutect2
- OR6C70 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- PHTF2 | c.1466G>C p.R489T (on ENST00000248550 / NM_001366089.1; = p.R451T on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PLK4 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- PNN | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POU5F2 | c.427T>A p.S143T | Missense Mutation (SNP) | VAF 57/493 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PPP1R10 | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PPP6C | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRCC | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PRDM2 | c.3232C>G p.L1078V | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRSS56 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- PSD | c.2820G>C p.Q940H | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- RABL2B | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 26/669 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAP1A | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RBBP7 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.298); called by muse, mutect2
- RPTN | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 50/534 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.587); called by muse, mutect2
- S100A7A | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SALL2 | c.84C>G p.S28R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.385); called by muse, varscan2
- SASH1 | c.36G>C p.E12D | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA4C | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 16/572 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SERAC1 | c.853-1G>C p.X285_splice | Splice Site (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- SHISA7 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SLIT2 | c.1720G>T p.E574* | Nonsense Mutation (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- SMARCAL1 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 26/502 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2
- SPAG17 | c.3320-1G>C p.X1107_splice | Splice Site (SNP) | VAF 29/141 reads (21%) | called by muse, mutect2, varscan2
- SPOCK3 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRPRA | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- SYCP2L | c.1664G>A p.S555N | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); called by muse, mutect2
- TAS2R19 | c.834C>G p.I278M | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- THAP11 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THUMPD3 | c.318C>G p.F106L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- TLE4 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 62/413 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TLR2 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- TP53 | c.336_349del p.F113Dfs*31 | Frame Shift Del (DEL) | VAF 50/122 reads (41%) | called by mutect2, pindel, varscan2
- TRPM7 | c.714G>C p.L238F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TTC14 | c.1552A>G p.R518G | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by mutect2, varscan2
- TTN | c.40596G>C p.K13532N (on ENST00000591111; = p.K6108N on NM_003319.4) | Missense Mutation (SNP) | VAF 20/179 reads (11%) | PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- TXNRD3 | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2
- UBQLN3 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- UBQLN4 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2
- UBR4 | c.3550G>C p.E1184Q | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.954); called by muse, mutect2
- UNC80 | c.9136G>A p.E3046K | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- USHBP1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.429); called by muse, mutect2
- VEZT | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 25/135 reads (19%) | called by muse, mutect2, varscan2
- VWA3B | c.2449G>T p.E817* | Nonsense Mutation (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- WDFY4 | c.641C>G p.S214* | Nonsense Mutation (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- WDR18 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- WDR19 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- WDR35 | c.3028G>C p.E1010Q (on ENST00000345530 / NM_001006657.2; = p.E999Q on NM_020779.4) | Missense Mutation (SNP) | VAF 56/527 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- WNK2 | c.4204C>T p.Q1402* (on ENST00000297954 / NM_001282394.1; = p.Q1365* on NM_006648.3) | Nonsense Mutation (SNP) | VAF 14/163 reads (9%) | called by muse, mutect2
- XAGE2 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); called by muse, mutect2
- YTHDF3 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 48/573 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB18 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- ZNF469 | c.7784C>G p.S2595C (on ENST00000437464; = p.S2623C on NM_001367624.2) | Missense Mutation (SNP) | VAF 22/868 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.18); called by muse, mutect2
- ZNF564 | c.460C>G p.Q154E | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2
- ZNF630 | c.1777C>G p.H593D | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2
- ZNF816-ZNF321P | c.683G>C p.R228T | Missense Mutation (SNP) | VAF 24/747 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.107); called by muse, mutect2
- ADAMTS9 | c.1119G>A p.S373= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as rs137935402; called by muse, mutect2, varscan2
- ADRA1B | c.759G>A p.L253= | Silent (SNP) | VAF 46/240 reads (19%) | called by muse, mutect2, varscan2
- AKNAD1 | c.516C>T p.L172= | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- AL121899.2 | c.936G>A p.V312= | Silent (SNP) | VAF 56/382 reads (15%) | called by muse, mutect2, varscan2
- ALG1L | c.291G>A p.V97= | Silent (SNP) | VAF 18/422 reads (4%) | catalogued as COSV61075935; called by muse, mutect2
- ALKAL2 | c.132C>T p.L44= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs973762345; called by muse, mutect2, varscan2
- AMBP | c.471G>A p.L157= | Silent (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.810C>T p.F270= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as rs1459049133; called by muse, mutect2, varscan2
- CCDC39 | c.237G>A p.E79= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- CCR6 | c.393C>T p.C131= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as rs143644849; called by muse, mutect2, varscan2
- CD72 | c.417G>A p.L139= | Silent (SNP) | VAF 40/242 reads (17%) | called by muse, mutect2, varscan2
- CD96 | c.201G>C p.L67= | Silent (SNP) | VAF 39/302 reads (13%) | catalogued as COSV51921312; called by muse, mutect2, varscan2
- CDON | c.3126C>T p.L1042= | Silent (SNP) | VAF 62/597 reads (10%) | called by muse, mutect2
- CDV3 | c.645G>A p.K215= | Silent (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- CEP250 | c.5562G>A p.L1854= | Silent (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2
- CFAP46 | c.5778G>A p.L1926= | Silent (SNP) | VAF 23/122 reads (19%) | called by muse, mutect2, varscan2
- CMPK1 | c.96C>T p.L32= | Silent (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- COBLL1 | c.1260G>A p.V420= (on ENST00000392717; = p.V382= on NM_014900.5) | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- COCH | c.1296C>T p.N432= (on ENST00000216361 / NM_001347720.1; = p.N367= on NM_004086.3) | Silent (SNP) | VAF 69/536 reads (13%) | called by muse, mutect2, varscan2
- COG7 | c.660C>A p.L220= | Silent (SNP) | VAF 60/350 reads (17%) | called by muse, mutect2, varscan2
- COL1A1 | c.4320C>T p.I1440= | Silent (SNP) | VAF 60/467 reads (13%) | catalogued as rs770326881; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP1B1 | c.1191C>T p.V397= | Silent (SNP) | VAF 25/180 reads (14%) | catalogued as COSV52226051; called by muse, mutect2, varscan2
- DGKQ | c.837G>A p.G279= | Silent (SNP) | VAF 49/195 reads (25%) | called by muse, mutect2, varscan2
- DOP1A | c.3198G>A p.E1066= | Silent (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2
- EIF4G1 | c.2145C>A p.I715= (on ENST00000346169 / NM_198241.3; = p.I520= on NM_004953.5) | Silent (SNP) | VAF 21/421 reads (5%) | catalogued as COSV59993279; called by muse, mutect2
- ENDOD1 | c.711C>G p.V237= | Silent (SNP) | VAF 82/387 reads (21%) | called by muse, mutect2, varscan2
- ERCC2 | c.2253G>A p.K751= | Silent (SNP) | VAF 19/265 reads (7%) | catalogued as rs1182084610; called by muse, mutect2
- FBXL8 | c.420C>T p.L140= | Silent (SNP) | VAF 36/301 reads (12%) | called by muse, mutect2, varscan2
- FUT10 | c.1431C>T p.F477= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV100567639; called by muse, mutect2, varscan2
- GALNT16 | c.708G>C p.V236= | Silent (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- GC | c.780C>T p.N260= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as rs1193260553; called by muse, mutect2, varscan2
- GRIN2C | c.1593C>T p.I531= | Silent (SNP) | VAF 15/244 reads (6%) | catalogued as COSV53109656; called by muse, mutect2
- HDC | c.1470C>T p.L490= | Silent (SNP) | VAF 26/340 reads (8%) | called by muse, mutect2
- HIGD1C | c.87C>T p.V29= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs749415492; called by muse, mutect2, varscan2
- HTR1B | c.271C>T p.L91= | Silent (SNP) | VAF 40/561 reads (7%) | catalogued as COSV64051678, COSV64051750; called by muse, mutect2
- KLK4 | c.720C>G p.L240= | Silent (SNP) | VAF 64/1196 reads (5%) | called by muse, mutect2
- KRTAP10-7 | c.936C>T p.L312= | Silent (SNP) | VAF 119/746 reads (16%) | called by muse, mutect2, varscan2
- LDB3 | c.504G>A p.L168= | Silent (SNP) | VAF 16/384 reads (4%) | catalogued as COSV99555634, COSV99556096; called by muse, mutect2
- LILRB1 | c.2091T>C p.T697= (on ENST00000427581; = p.T646= on NM_006669.6) | Silent (SNP) | VAF 52/668 reads (8%) | catalogued as rs758057879; called by muse, mutect2
- LRRC8E | c.135C>G p.L45= | Silent (SNP) | VAF 23/193 reads (12%) | called by muse, mutect2, varscan2
- LVRN | c.2919G>A p.L973= | Silent (SNP) | VAF 38/218 reads (17%) | called by muse, mutect2, varscan2
- LYPD3 | c.114G>A p.Q38= | Silent (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2
- MCM4 | c.798G>A p.L266= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- MTMR8 | c.105G>A p.L35= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV66396045; called by muse, mutect2, varscan2
- MYO7B | c.4221C>G p.L1407= | Silent (SNP) | VAF 20/253 reads (8%) | called by muse, mutect2
- NSMF | c.1332G>A p.L444= (on ENST00000371475 / NM_001130969.3; = p.L442= on NM_015537.4) | Silent (SNP) | VAF 63/422 reads (15%) | called by muse, mutect2, varscan2
- NT5C2 | c.1305G>A p.G435= | Silent (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- NXF3 | c.18A>G p.G6= | Silent (SNP) | VAF 29/266 reads (11%) | called by muse, mutect2, varscan2
- NYX | c.870C>T p.I290= | Silent (SNP) | VAF 76/938 reads (8%) | catalogued as COSV61181538; called by muse, mutect2
- OR2AG1 | c.405C>T p.L135= | Silent (SNP) | VAF 15/296 reads (5%) | catalogued as rs1381813804; called by muse, mutect2
- OR4D11 | c.405C>T p.I135= | Silent (SNP) | VAF 29/328 reads (9%) | catalogued as COSV57584463; called by muse, mutect2
- PAPPA | c.1104G>A p.P368= | Silent (SNP) | VAF 24/750 reads (3%) | catalogued as rs1232382704, COSV60291676; called by muse, mutect2
- PIP4K2B | c.846G>A p.L282= | Silent (SNP) | VAF 38/316 reads (12%) | catalogued as rs1386092689; called by muse, mutect2, varscan2
- PLCD1 | c.1458C>T p.L486= | Silent (SNP) | VAF 72/424 reads (17%) | called by muse, mutect2, varscan2
- PLXDC2 | c.1551T>A p.V517= | Silent (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- PNMA3 | c.495A>G p.R165= | Silent (SNP) | VAF 67/355 reads (19%) | called by muse, mutect2, varscan2
- PODNL1 | c.270C>T p.L90= | Silent (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- POGLUT3 | c.642C>T p.F214= | Silent (SNP) | VAF 34/179 reads (19%) | called by muse, mutect2, varscan2
- PPP1R9B | c.927G>A p.S309= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as rs1191674117; called by muse, mutect2
- PTPRB | c.417C>T p.V139= | Silent (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- RNF213 | c.15105G>A p.L5035= | Silent (SNP) | VAF 22/600 reads (4%) | called by muse, mutect2
- SAMD4A | c.1065C>T p.L355= | Silent (SNP) | VAF 10/234 reads (4%) | catalogued as rs1337680107; called by muse, mutect2
- SCN3A | c.2802G>C p.L934= | Silent (SNP) | VAF 60/471 reads (13%) | catalogued as COSV51822712; called by muse, mutect2, varscan2
- SCNN1G | c.1647C>T p.I549= | Silent (SNP) | VAF 108/747 reads (14%) | catalogued as COSV55598130; called by muse, mutect2, varscan2
- SEMA6A | c.936G>A p.L312= | Silent (SNP) | VAF 33/164 reads (20%) | called by muse, mutect2, varscan2
- SLC26A11 | c.1461C>T p.S487= | Silent (SNP) | VAF 30/201 reads (15%) | catalogued as rs777928925, COSV63279785; called by muse, mutect2, varscan2
- SLC9A5 | c.1704C>T p.V568= | Silent (SNP) | VAF 41/233 reads (18%) | called by muse, mutect2, varscan2
- SLIT2 | c.4257C>A p.I1419= | Silent (SNP) | VAF 71/366 reads (19%) | called by muse, mutect2, varscan2
- SMARCA2 | c.2685C>T p.L895= | Silent (SNP) | VAF 28/370 reads (8%) | called by muse, mutect2
- SPATC1 | c.547C>T p.L183= | Silent (SNP) | VAF 24/305 reads (8%) | catalogued as COSV104426700, COSV66299048; called by muse, mutect2
- SPSB2 | c.791G>A p.*264= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as rs782521294; called by muse, mutect2
- STAP2 | c.519G>A p.G173= | Silent (SNP) | VAF 30/289 reads (10%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.594C>T p.I198= | Silent (SNP) | VAF 35/244 reads (14%) | catalogued as rs760748430, COSV65234242; called by muse, mutect2, varscan2
- THBS4 | c.2673G>A p.V891= | Silent (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- TLE5 | c.219C>T p.I73= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1401494957; called by muse, varscan2
- TMEM132B | c.9T>G p.G3= | Silent (SNP) | VAF 43/161 reads (27%) | called by muse, mutect2, varscan2
- TMEM204 | c.126C>T p.S42= | Silent (SNP) | VAF 46/351 reads (13%) | catalogued as rs372798914; called by muse, mutect2, varscan2
- TRAPPC8 | c.117C>T p.F39= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as rs1424235559, COSV99351805; called by muse, mutect2, varscan2
- TRIOBP | c.546G>A p.P182= | Silent (SNP) | VAF 76/438 reads (17%) | catalogued as rs770822990, COSV60381988; called by muse, mutect2, varscan2
- UPF1 | c.1753C>T p.L585= (on ENST00000599848 / NM_001297549.2; = p.L574= on NM_002911.4) | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as COSV53198320; called by muse, mutect2, varscan2
- USH2A | c.9489G>A p.Q3163= | Silent (SNP) | VAF 12/338 reads (4%) | catalogued as COSV56388245; called by muse, mutect2
- USP54 | c.1266C>T p.V422= | Silent (SNP) | VAF 22/167 reads (13%) | called by muse, mutect2, varscan2
- VPS13B | c.9906G>A p.P3302= | Silent (SNP) | VAF 104/330 reads (32%) | catalogued as rs775601813, COSV62158804; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ZFP28 | c.640C>T p.L214= | Silent (SNP) | VAF 16/167 reads (10%) | catalogued as COSV100019259; called by muse, mutect2, varscan2
- ZNF146 | c.12C>T p.L4= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV61932567; called by muse, mutect2, varscan2
- ZNF701 | c.804C>T p.L268= (on ENST00000301093; = p.L202= on NM_018260.3) | Silent (SNP) | VAF 456/600 reads (76%) | catalogued as COSV56527711; called by mutect2, varscan2
- ADA | c.975+13G>C | Intron (SNP) | VAF 46/697 reads (7%) | catalogued as rs202006713; called by muse, mutect2
- ADD3-AS1 | chr10:109942758 G>A | 3'Flank (SNP) | VAF 78/433 reads (18%) | called by muse, mutect2, varscan2
- AGPAT3 | c.*2841G>C | 3'UTR (SNP) | VAF 30/221 reads (14%) | called by muse, mutect2, varscan2
- AMH | c.413-25G>A | Intron (SNP) | VAF 89/508 reads (18%) | catalogued as rs1410676851; called by muse, mutect2, varscan2
- ATP6V0E1 | c.*64G>A | 3'UTR (SNP) | VAF 23/152 reads (15%) | called by muse, mutect2, varscan2
- C1RL | c.*1236G>A | 3'UTR (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- CAPRIN2 | c.2148+1626C>T | Intron (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- CASP7 | c.-115G>A | 5'UTR (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- CNFN | c.-2-499C>G | Intron (SNP) | VAF 15/126 reads (12%) | catalogued as COSV99706187; called by muse, mutect2, varscan2
- DUOX2 | c.1131+20C>T | Intron (SNP) | VAF 14/298 reads (5%) | called by muse, mutect2
- EMD | c.399+21C>A | Intron (SNP) | VAF 63/451 reads (14%) | called by muse, mutect2, varscan2
- FILIP1L | chr3:99830532 G>C | 3'Flank (SNP) | VAF 20/292 reads (7%) | called by muse, mutect2
- KRBOX4 | c.253+52C>G | Intron (SNP) | VAF 32/408 reads (8%) | called by muse, mutect2
- LDLRAP1 | c.747+42G>A | Intron (SNP) | VAF 78/474 reads (16%) | called by muse, mutect2, varscan2
- LINC02870 | n.156C>T | RNA (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- MFSD8 | c.1351-21C>T | Intron (SNP) | VAF 17/154 reads (11%) | called by muse, mutect2, varscan2
- MIR515-1 | n.35C>G | RNA (SNP) | VAF 31/508 reads (6%) | catalogued as rs950125064; called by muse, mutect2
- MPDU1 | c.303-40C>G | Intron (SNP) | VAF 16/413 reads (4%) | catalogued as rs1211812481; called by muse, mutect2
- NPDC1 | c.113-341G>C | Intron (SNP) | VAF 14/107 reads (13%) | called by mutect2, varscan2
- NT5C3A | c.-63G>A | 5'UTR (SNP) | VAF 81/345 reads (23%) | catalogued as COSV54239830; called by muse, mutect2, varscan2
- PARP8 | c.147-8279C>T | Intron (SNP) | VAF 10/28 reads (36%) | catalogued as rs746737399; called by muse, varscan2
- PPP4R1L | n.767C>G | RNA (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- SAMD4A | c.2045-115G>C | Intron (SNP) | VAF 44/468 reads (9%) | catalogued as rs780308225; called by muse, mutect2
- SCARF2 | c.*43C>T | 3'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- SINHCAF | c.-21+795C>T | Intron (SNP) | VAF 10/153 reads (7%) | called by muse, mutect2
- SMC1A | c.1732-31G>C | Intron (SNP) | VAF 47/1078 reads (4%) | called by muse, mutect2
- THSD4 | c.-80+15121C>T | Intron (SNP) | VAF 16/156 reads (10%) | called by muse, mutect2, varscan2
- TIPIN | c.475+1736G>A | Intron (SNP) | VAF 16/70 reads (23%) | called by muse, mutect2, varscan2
- TMEM120A | c.*79G>A | 3'UTR (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- XIST | n.9459A>G | RNA (SNP) | VAF 83/575 reads (14%) | called by muse, mutect2, varscan2
- ZNF423 | c.*10C>G | 3'UTR (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- ZNF521 | c.*15C>T | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
